Somatic mutation profile of tumor specimen TCGA-CR-5243-01A (aliquot TCGA-CR-5243-01A-01D-1512-08) from TCGA case TCGA-CR-5243, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G3; Age at diagnosis: 51.5 years (18,812 days).
Specimen TCGA-CR-5243-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e537778-0253-48fe-a376-e577bc4d4e86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-5243-10A (Blood Derived Normal), aliquot TCGA-CR-5243-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67af9250-939b-414d-9e51-9fdc34cf9532

The open-access MAF lists 64 somatic variants for this specimen: 47 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 41, Silent 17, Nonsense Mutation 4, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 43/135 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGO3 | c.814C>G p.H272D | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99868206; called by muse, mutect2, varscan2
- ARID5B | c.3065T>C p.V1022A | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99689243; called by muse, mutect2, varscan2
- ASB5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as COSV99641413; called by muse, varscan2
- BTAF1 | c.1193T>G p.L398R | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV99795075; called by muse, mutect2, varscan2
- CLDN15 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as rs747527920, COSV100385194; called by muse, mutect2, varscan2
- CLEC14A | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100643514, COSV60564477; called by muse, mutect2
- CPT1C | c.2199C>G p.I733M | Missense Mutation (SNP) | VAF 128/354 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99773311; called by muse, mutect2, varscan2
- DIP2B | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs145274091; called by muse, mutect2, varscan2
- EIF2B5 | c.746G>A p.R249Q (on ENST00000647909; = p.R241Q on NM_003907.3) | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV56606505; called by muse, mutect2, varscan2
- ENDOV | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100108485; called by muse, mutect2
- EVC2 | c.1133A>C p.Q378P | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100185358; called by muse, mutect2, varscan2
- FGD5 | c.3522C>A p.Y1174* | Nonsense Mutation (SNP) | VAF 23/35 reads (66%) | catalogued as COSV99547578; called by muse, mutect2, varscan2
- FNIP1 | c.3175G>C p.V1059L | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100330318; called by muse, mutect2, varscan2
- FSCB | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 153/376 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV100469019; called by muse, mutect2, varscan2
- FSTL4 | c.194G>T p.C65F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99531787; called by muse, mutect2, varscan2
- GK5 | c.1506G>T p.Q502H | Missense Mutation (SNP) | VAF 91/316 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV101242135; called by muse, mutect2, varscan2
- GLI3 | c.3139C>A p.Q1047K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV101229768, COSV101229994; called by muse, mutect2, varscan2
- H4C3 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100619502; called by muse, mutect2, varscan2
- HFM1 | c.4164C>A p.N1388K | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99645613; called by muse, mutect2, varscan2
- HS6ST1 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52130520, COSV99389444; called by muse, mutect2, varscan2
- IL1RAP | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 131/487 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201706120, COSV50762742; called by muse, mutect2, varscan2
- IL22RA1 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as rs201599737, COSV54628329, COSV99583316; called by muse, mutect2, varscan2
- JADE1 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1362304065, COSV99885498; called by muse, mutect2, varscan2
- KDM6B | c.2005C>T p.R669* | Nonsense Mutation (SNP) | VAF 68/158 reads (43%) | catalogued as COSV99640928; called by muse, mutect2, varscan2
- KMT2D | c.15928G>A p.G5310R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435849650, COSV99978751; called by muse, mutect2, varscan2
- MAG | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as rs147583558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K12 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as rs1371761787, COSV99913058; called by muse, mutect2, varscan2
- MYH14 | c.527C>A p.A176E | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99222126; called by muse, mutect2, varscan2
- NCAPH2 | c.1652G>C p.R551P | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99329404; called by muse, mutect2, varscan2
- NOTCH1 | c.3255C>G p.C1085W | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99486218; called by muse, mutect2, varscan2
- OR2F1 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101231330, COSV67331559, COSV67332142; called by muse, mutect2, varscan2
- PARP4 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs145170390, COSV101131787, COSV67962312; called by muse, mutect2, varscan2
- PIH1D1 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99221037; called by mutect2, varscan2
- PLAAT1 | c.574G>C p.D192H (on ENST00000650797; = p.D87H on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53229985, COSV53231805, COSV99290587; called by muse, mutect2, varscan2
- PLAGL2 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); catalogued as rs1238663936, COSV99867020; called by muse, mutect2, varscan2
- PTCHD1 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101037374; called by muse, mutect2, varscan2
- PTPN13 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.146); catalogued as rs371279294; called by muse, mutect2, varscan2
- REG1B | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100521292; called by muse, mutect2, varscan2
- ROCK1 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101296275; called by muse, mutect2, varscan2
- SLC22A5 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs386134203, CM104587; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAF3 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 170/208 reads (82%) | catalogued as COSV61024890; called by mutect2, varscan2
- UFL1 | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV100990029; called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by pindel, varscan2
- CD163 | c.2188G>T p.G730W | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HNF1B | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ZNF221 | c.373del p.I125Yfs*9 | Frame Shift Del (DEL) | VAF 42/162 reads (26%) | called by mutect2, pindel, varscan2
- ACVRL1 | c.435G>A p.R145= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as CD052978, COSV66359848; called by muse, mutect2, varscan2
- AKT3 | c.918C>T p.F306= | Silent (SNP) | VAF 42/187 reads (22%) | catalogued as rs1347029113, COSV99794565; called by muse, mutect2, varscan2
- ATP11A | c.3216C>T p.S1072= | Silent (SNP) | VAF 73/102 reads (72%) | catalogued as rs185868076; called by muse, mutect2, varscan2
- DNAH5 | c.3693C>T p.N1231= | Silent (SNP) | VAF 40/243 reads (16%) | catalogued as rs969699608, COSV54261360; called by muse, mutect2, varscan2
- DNM2 | c.627G>C p.L209= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV100116960; called by muse, mutect2, varscan2
- DOCK2 | c.5400G>A p.R1800= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV56990886; called by muse, mutect2, varscan2
- GRN | c.324C>T p.D108= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs578182427, COSV99274662; called by muse, mutect2, varscan2
- LDB1 | c.1125C>T p.S375= (on ENST00000425280 / NM_001321612.2; = p.S341= on NM_003893.5) | Silent (SNP) | VAF 76/201 reads (38%) | catalogued as COSV100756349; called by muse, mutect2, varscan2
- LRRC41 | c.2004G>A p.Q668= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100586176; called by muse, mutect2, varscan2
- MLST8 | c.855C>T p.I285= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as rs200094349; called by muse, mutect2, varscan2
- OR2A7 | c.699G>A p.Q233= | Silent (SNP) | VAF 52/348 reads (15%) | catalogued as rs1382133598, COSV101512197; called by muse, mutect2, varscan2
- PELI2 | c.393C>T p.I131= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99953089; called by muse, mutect2, varscan2
- RALBP1 | c.1860G>A p.P620= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs775458653, COSV50038738; called by muse, mutect2, varscan2
- SCAF8 | c.1986G>A p.S662= | Silent (SNP) | VAF 93/305 reads (30%) | catalogued as rs201177064, COSV100781295; called by muse, mutect2, varscan2
- TIMP2 | c.552C>T p.N184= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as rs373804430; called by muse, mutect2, varscan2
- TRIOBP | c.6150C>G p.L2050= (on ENST00000644935 / NM_001039141.3; = p.L337= on NM_007032.5) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100462255; called by muse, mutect2, varscan2
- YWHAQ | c.90C>G p.T30= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs1341882686, COSV53003590; called by muse, mutect2, varscan2
